Somatic mutation profile of tumor specimen TCGA-FP-7916-01A (aliquot TCGA-FP-7916-01A-11D-2201-08) from TCGA case TCGA-FP-7916, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.0 years (28,475 days).
Specimen TCGA-FP-7916-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 528ce6d5-cd7f-4853-97fb-5c5f39ef3999.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FP-7916-10A (Blood Derived Normal), aliquot TCGA-FP-7916-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f523621-6eca-4cea-a243-45f8b2ee34d0

The open-access MAF lists 94 somatic variants for this specimen: 71 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 22, Splice Site 2, In Frame Del 2, Frame Shift Del 2, Translation Start Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CDH9 | c.302T>A p.F101Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50283484; called by muse, mutect2, varscan2
- CNTFR | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1477765579, COSV63633792; called by muse, mutect2, varscan2
- CNTN6 | c.1255T>G p.S419A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1397026734, COSV63164761; called by muse, mutect2, varscan2
- COL4A4 | c.1548C>A p.D516E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61632105; called by mutect2, varscan2
- DAAM2 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51317290; called by muse, mutect2
- DLC1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 4/62 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs980546340, COSV52303541; called by muse, mutect2
- DMD | c.5740G>T p.E1914* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV63754476; called by muse, mutect2, varscan2
- DNAH2 | c.12814C>T p.R4272W | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs145079158; called by muse, mutect2, varscan2
- DNAH8 | c.10057G>A p.A3353T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776294190, COSV59444496; called by muse, mutect2, varscan2
- DSP | c.4610G>A p.R1537H | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.902); catalogued as rs762135558, COSV65792655; ClinVar: uncertain significance; called by muse, varscan2
- DST | c.1408C>T p.R470C (on ENST00000361203 / NM_001374722.1; = p.R144C on NM_001723.6) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs543868808, COSV99753962; ClinVar: uncertain significance; called by mutect2, varscan2
- EBF1 | c.587A>C p.Q196P | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58178120; called by muse, mutect2, varscan2
- EBF3 | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62474961; called by muse, mutect2
- FLRT2 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as rs201981148, COSV58140190; called by muse, mutect2, varscan2
- FMO4 | c.1645T>C p.S549P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs758181610, COSV63001139; called by muse, mutect2, varscan2
- FUT9 | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV56146746; called by muse, mutect2, varscan2
- GPR139 | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV58502859; called by muse, mutect2
- HP1BP3 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs768170754, COSV56562462; called by mutect2, varscan2
- IGSF9 | c.3272A>C p.E1091A (on ENST00000368094 / NM_001135050.2; = p.E1075A on NM_020789.4) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs878975452, COSV57422253; called by muse, mutect2
- KCNG1 | c.1340G>C p.S447T | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV65369069; called by muse, mutect2
- KLHL3 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs370693843; called by muse, mutect2, varscan2
- KMT2C | c.7489C>T p.R2497C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs150994342; called by muse, mutect2, varscan2
- LMCD1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs150819156; called by muse, mutect2, varscan2
- LNX2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs1484111162, COSV60335698; called by muse, mutect2, varscan2
- LRRC4B | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); catalogued as rs763207062, COSV65349197; called by muse, mutect2, varscan2
- MARK2 | c.1571C>T p.A524V (on ENST00000402010 / NM_001039469.2; = p.A490V on NM_017490.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs373710920; called by muse, mutect2, varscan2
- MUSK | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV51885800; called by muse, mutect2, varscan2
- NAV3 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as COSV57079145; called by muse, mutect2, varscan2
- NLRP12 | c.2896C>A p.Q966K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV60747274; called by muse, mutect2, varscan2
- NOTCH2 | c.2426C>A p.T809N | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV56691122; called by muse, mutect2
- NRP1 | c.2594G>A p.S865N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55166673; called by muse, mutect2, varscan2
- OR2M2 | c.911T>A p.I304N | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV62898342; called by muse, mutect2
- OR8H1 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100476996, COSV100477395; called by muse, mutect2
- OSR2 | c.314T>A p.V105D | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV52556958; called by muse, mutect2, varscan2
- PACRG | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs143276239, COSV61304751; called by muse, mutect2, varscan2
- PAX6 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV53793356; called by muse, mutect2
- PCDHB13 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as rs1243709145; called by muse, mutect2, varscan2
- PCDHGB2 | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.395); catalogued as COSV53945928; called by muse, varscan2
- PRCC | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.727); catalogued as COSV99618588; called by muse, mutect2, varscan2
- RABGAP1L | c.657G>C p.E219D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as rs908267609, COSV99269225; called by muse, mutect2, varscan2
- RAVER2 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV53807306; called by muse, mutect2
- RDH16 | c.97T>C p.F33L | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV62458119; called by muse, mutect2, varscan2
- RNF183 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs778064706, COSV52907731; called by muse, mutect2, varscan2
- RPS6KA6 | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV53119790; called by muse, mutect2, varscan2
- RSF1 | c.4205C>A p.A1402E | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV57839828; called by muse, mutect2, varscan2
- SIGLEC8 | c.455-1G>T p.X152_splice | Splice Site (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100367219; called by muse, mutect2, varscan2
- SIX6 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs779887646, COSV59802149; called by muse, mutect2, varscan2
- SLC9A4 | c.1670A>G p.E557G | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV54833755; called by muse, mutect2, varscan2
- SLC9A8 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV64288379; called by muse, mutect2
- SMC4 | c.2480G>A p.R827H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs143540491, COSV61002928; called by muse, varscan2
- SNTG1 | c.1141T>G p.W381G | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52442871; called by muse, mutect2, varscan2
- SOD2 | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61623008; called by muse, mutect2, varscan2
- SPATA31E1 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as rs770273431, COSV57791369; called by mutect2, varscan2
- SYT17 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as COSV62546193; called by muse, mutect2, varscan2
- TBCB | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs750629354, COSV55692370; called by muse, mutect2, varscan2
- TMEM100 | c.296del p.L99Yfs*2 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs894486999; called by mutect2, pindel, varscan2
- TMIGD3 | c.323G>A p.R108Q (on ENST00000369717 / NM_001081976.2; = p.R189Q on NM_020683.7) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as rs780824295, COSV63163325; called by muse, mutect2, varscan2
- TNFSF4 | c.118T>C p.F40L | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56056516; called by muse, mutect2
- TREX2 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs782755741, COSV100443935, COSV57849083; called by muse, mutect2, varscan2
- TTN | c.85096G>C p.V28366L (on ENST00000591111; = p.V20942L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | PolyPhen probably damaging (0.99); catalogued as COSV60052902; called by muse, mutect2, varscan2
- TTN | c.57058C>A p.L19020M (on ENST00000591111; = p.L11596M on NM_003319.4) | Missense Mutation (SNP) | VAF 10/128 reads (8%) | PolyPhen probably damaging (0.976); catalogued as COSV60041194, COSV60052977; called by muse, mutect2
- UBQLN3 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV100293534; called by muse, mutect2, varscan2
- USP4 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs747632858, COSV55537009; called by muse, mutect2, varscan2
- ZNF626 | c.847A>G p.K283E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV74129473; called by muse, mutect2, varscan2
- ZNF804B | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs755925564, COSV60827517, COSV60840429; called by muse, mutect2, varscan2
- ARID1A | c.5113_5124+2del p.X1705_splice | Splice Site (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- C2orf16 | c.5310_5357del p.R1772_E1787del | In Frame Del (DEL) | VAF 55/231 reads (24%) | called by muse*, mutect2
- DMTN | c.1201_1203del p.K401del | In Frame Del (DEL) | VAF 13/69 reads (19%) | called by pindel, varscan2
- RIF1 | c.2795C>A p.A932D | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- TRIOBP | c.3238del p.T1080Pfs*133 | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | called by mutect2, pindel, varscan2
- ADGRG5 | c.1260C>T p.G420= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs763751363, COSV61082589; called by muse, mutect2, varscan2
- AOPEP | c.1329C>T p.I443= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as rs777304173, COSV52917802; called by muse, mutect2, varscan2
- CNOT1 | c.7065G>A p.S2355= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs762569016, COSV54700080; called by muse, mutect2, varscan2
- CTNS | c.213G>A p.E71= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV50440519; called by muse, mutect2, varscan2
- FAT4 | c.12327T>A p.V4109= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV58684488; called by muse, varscan2
- GRIK2 | c.2268C>T p.G756= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as rs758586743, COSV100024840; called by muse, mutect2, varscan2
- KCNJ15 | c.396C>A p.V132= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV60810746, COSV60810842; called by muse, mutect2, varscan2
- KCNQ3 | c.1659G>A p.G553= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as COSV66470564; called by muse, mutect2, varscan2
- MPP2 | c.1608C>T p.Y536= (on ENST00000461854 / NM_001278372.2; = p.Y512= on NM_005374.5) | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as rs554116449, COSV52235739; called by muse, mutect2, varscan2
- NTRK3 | c.1785G>T p.L595= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV100712600, COSV100712760; called by muse, mutect2, varscan2
- OR10G8 | c.717C>A p.T239= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV70908535; called by muse, mutect2, varscan2
- PCDHB1 | c.141C>T p.N47= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV60630830; called by muse, mutect2, varscan2
- PNMA5 | c.759G>A p.P253= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs782116075, COSV62625358; called by muse, mutect2, varscan2
- RBMXL2 | c.60C>T p.D20= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs748334091, COSV60980006; called by muse, mutect2, varscan2
- REPIN1 | c.525G>A p.R175= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV68292247; called by muse, mutect2
- SLC2A13 | c.1182C>A p.T394= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55117381; called by muse, mutect2, varscan2
- SLC4A3 | c.2130C>T p.A710= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs779177986, COSV56093681; called by muse, mutect2, varscan2
- SPECC1 | c.1158C>T p.S386= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV54957911; called by muse, mutect2
- SYT9 | c.636C>T p.D212= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs548666564, COSV59614744; called by mutect2, varscan2
- TGFBR2 | c.219C>T p.I73= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55449481; called by muse, mutect2, varscan2
- VWA3B | c.2625C>A p.T875= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as COSV68242899; called by muse, mutect2, varscan2
- ZNF446 | c.1017C>T p.R339= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1205411775, COSV59991445; called by muse, mutect2
- MIR519A1 | n.47G>T | RNA (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
